Somatic mutation profile of tumor specimen TCGA-91-6849-01A (aliquot TCGA-91-6849-01A-11D-1945-08) from TCGA case TCGA-91-6849, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.8 years (27,676 days).
Specimen TCGA-91-6849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 343bc0d2-67fc-4446-bfb7-1e1c57ace519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6849-11A (Solid Tissue Normal), aliquot TCGA-91-6849-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bee4438b-3fbe-4a18-ba0e-749b7c399520

The open-access MAF lists 124 somatic variants for this specimen: 96 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 23, Nonsense Mutation 6, Splice Site 5, Frame Shift Del 3, Splice Region 3, RNA 2, In Frame Del 1, 5'UTR 1, Nonstop Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP11C | c.1253C>A p.T418N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1556323334, CM165573, COSV59575254; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2936C>G p.S979C (on ENST00000404938 / NM_001163941.2; = p.S534C on NM_178559.6) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51721769; called by muse, mutect2, varscan2
- ACTN1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51991475, COSV51998345; called by muse, mutect2, varscan2
- ADAM12 | c.2728T>A p.*910Rext*9 | Nonstop Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV64137848; called by muse, mutect2, varscan2
- AGBL1 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV69815425; called by muse, mutect2, varscan2
- ANKIB1 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs369834494; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV57596634; called by muse, mutect2, varscan2
- ATP1B1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 74/327 reads (23%) | catalogued as COSV63171093; called by muse, mutect2, varscan2
- BCAP31 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61452546; called by muse, mutect2, varscan2
- C3orf20 | c.1296C>A p.H432Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53783528; called by muse, mutect2, varscan2
- CILP2 | c.1861G>T p.A621S | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV52280940; called by muse, mutect2, varscan2
- CLCN5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as CM983858, COSV56587030; called by muse, mutect2, varscan2
- COLGALT2 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62731512; called by muse, mutect2, varscan2
- CORO7 | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as COSV52034421; called by muse, mutect2, varscan2
- CPSF2 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV54101022; called by muse, mutect2, varscan2
- CST4 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV54150589; called by muse, mutect2, varscan2
- CTNNA1 | c.2059C>G p.Q687E | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV57081964; called by muse, mutect2, varscan2
- ERBB4 | c.718G>T p.G240* | Nonsense Mutation (SNP) | VAF 58/163 reads (36%) | catalogued as COSV53516241, COSV53518427; called by muse, mutect2, varscan2
- ESYT3 | c.2048A>G p.K683R | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs774303241, COSV101272790; called by muse, varscan2
- ESYT3 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as COSV101272791, COSV67440892; called by muse, varscan2
- ESYT3 | c.2050A>C p.S684R | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101272792; called by muse, varscan2
- ETS2 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62874565; called by muse, mutect2, varscan2
- EYS | c.959G>C p.C320S | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60980216, COSV61001166; called by muse, mutect2, varscan2
- FAM110B | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64068366; called by muse, mutect2, varscan2
- FAM117B | c.879T>A p.S293R | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753503653, COSV57422634; called by muse, mutect2, varscan2
- FAM47B | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as COSV61457039; called by muse, mutect2, varscan2
- GDAP2 | c.471-1G>A p.X157_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as rs1403648471, COSV65613470; called by muse, mutect2, varscan2
- GIN1 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV67537861; called by muse, mutect2, varscan2
- GNG13 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99243869; called by muse, mutect2, varscan2
- GNG13 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99243871; called by muse, mutect2, varscan2
- HECW1 | c.353-1G>A p.X118_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV67834551, COSV67840918; called by muse, mutect2, varscan2
- HIVEP2 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV50072993, COSV99177178; called by muse, mutect2, varscan2
- IGF2BP3 | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV51694141; called by muse, mutect2, varscan2
- ING4 | c.632G>T p.G211V (on ENST00000396807 / NM_001127582.2; = p.G210V on NM_016162.4) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57525532; called by muse, mutect2, varscan2
- ITIH6 | c.2885C>A p.P962Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV54493659; called by muse, mutect2, varscan2
- IVNS1ABP | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV62252218; called by muse, mutect2, varscan2
- KEAP1 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50277303, COSV50652664, COSV99408437; called by muse, mutect2, varscan2
- KIAA1109 | c.5900G>A p.G1967E | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52694860; called by muse, mutect2, varscan2
- KLHL14 | c.1589-1G>C p.X530_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV63835776; called by muse, varscan2
- LILRA5 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.792); catalogued as COSV56645482; called by muse, mutect2, varscan2
- LILRB3 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as rs755749883; called by muse, mutect2, varscan2
- LRRK1 | c.5893G>T p.V1965L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV52627298; called by muse, mutect2, varscan2
- LZTR1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1329142115, COSV53152191; called by muse, mutect2, varscan2
- MAP3K4 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs779114335, COSV62333338, COSV62339022; called by muse, mutect2, varscan2
- MBL2 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as rs201511397, COSV64759471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEAK7 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471739259, COSV59145733; called by muse, mutect2, varscan2
- MFSD3 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV56743443; called by muse, mutect2, varscan2
- MLKL | c.1075A>T p.M359L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58206748; called by muse, mutect2, varscan2
- MXRA5 | c.2758C>G p.P920A | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54252232; called by muse, mutect2, varscan2
- MYO5B | c.4969A>G p.I1657V | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs75537257, COSV53232506; called by muse, mutect2, varscan2
- NEB | c.16750C>A p.L5584M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV51463441; called by muse, mutect2
- NIPA1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV61680819; called by muse, mutect2, varscan2
- NPAP1 | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 62/188 reads (33%) | catalogued as COSV61503965, COSV61511816; called by muse, mutect2, varscan2
- NRXN1 | c.1704G>T p.K568N | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as COSV58444076; called by muse, mutect2, varscan2
- OGT | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.228); catalogued as COSV65482797; called by muse, mutect2, varscan2
- OR52N2 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57678029; called by muse, mutect2, varscan2
- PCDHB13 | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.098); catalogued as COSV53395081, COSV53401447; called by muse, mutect2, varscan2
- PRICKLE3 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66235172; called by muse, mutect2, varscan2
- PSG4 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 145/262 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54941604; called by muse, mutect2, varscan2
- PTCHD3 | c.936G>T p.M312I | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV71257302; called by muse, mutect2, varscan2
- RASGRF2 | c.2549G>T p.C850F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV54140716, COSV99430998; called by muse, mutect2, varscan2
- SETBP1 | c.2186G>T p.R729M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99955468; called by muse, mutect2, varscan2
- SETBP1 | c.2187G>T p.R729S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56311937, COSV99955469; called by muse, mutect2, varscan2
- SH2D4A | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV56125099; called by muse, mutect2, varscan2
- SHPK | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1286449373, COSV50444697; called by muse, mutect2, varscan2
- SI | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs777987599, COSV52302866; called by muse, mutect2, varscan2
- SIGLEC11 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs770209602, COSV70222193; called by muse, mutect2, varscan2
- SLC11A1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750367937, COSV51919970; called by muse, mutect2, varscan2
- SLC25A23 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV51198292, COSV99902177; called by muse, mutect2, varscan2
- SLC27A6 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425261786, COSV52488261; called by muse, mutect2, varscan2
- SLC9C1 | c.1409T>A p.M470K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV59894020; called by muse, mutect2, varscan2
- SLITRK4 | c.603C>A p.H201Q | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV62026336; called by muse, mutect2, varscan2
- SORCS1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV53908592; called by muse, mutect2, varscan2
- SORCS1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as COSV53890482, COSV99548516; called by muse, mutect2, varscan2
- SPTBN2 | c.6372C>T p.D2124= | Splice Region (SNP) | VAF 15/71 reads (21%) | catalogued as rs770289355, COSV59461936; called by muse, mutect2, varscan2
- SRSF4 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65695850; called by muse, mutect2, varscan2
- SYP | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs782535583, COSV54297136; called by muse, mutect2, varscan2
- TLE4 | c.1590G>T p.L530= | Splice Region (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99513554; called by muse, mutect2, varscan2
- TLE4 | c.1590+1G>T p.X530_splice | Splice Site (SNP) | VAF 35/107 reads (33%) | catalogued as COSV99513557; called by muse, mutect2, varscan2
- TNR | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1454176598, COSV54898317; called by muse, mutect2
- TTN | c.17877A>T p.E5959D (on ENST00000591111; = p.E5032D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/245 reads (31%) | PolyPhen probably damaging (0.99); catalogued as COSV60375099; called by muse, mutect2, varscan2
- XPO1 | c.3162G>T p.M1054I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV68948038; called by muse, mutect2, varscan2
- XPO1 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV68948043; called by muse, mutect2, varscan2
- XPR1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62560885; called by muse, mutect2, varscan2
- ZFHX4 | c.8536G>T p.D2846Y | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99269218; called by muse, mutect2, varscan2
- ZNF543 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58629559; called by muse, mutect2, varscan2
- ZNF677 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.573); catalogued as COSV61721654, COSV61721752; called by muse, mutect2, varscan2
- BBS7 | c.1890del p.E631Nfs*12 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | called by mutect2, pindel, varscan2
- C7orf25 | c.123del p.K41Nfs*2 | Frame Shift Del (DEL) | VAF 95/354 reads (27%) | called by mutect2, pindel, varscan2
- IGLV5-52 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- LILRB4 | c.1044+3del | Splice Region (DEL) | VAF 56/200 reads (28%) | called by mutect2, pindel, varscan2
- RPL5 | c.706-4_724del p.X236_splice | Splice Site (DEL) | VAF 26/214 reads (12%) | called by mutect2, pindel
- SLC22A12 | c.425dup p.H142Qfs*177 | Frame Shift Ins (INS) | VAF 71/262 reads (27%) | called by mutect2, varscan2
- TBC1D2 | c.2227_2228del p.I743Hfs*4 | Frame Shift Del (DEL) | VAF 63/271 reads (23%) | called by mutect2, pindel, varscan2
- TNC | c.405_425del p.L136_A142del | In Frame Del (DEL) | VAF 60/336 reads (18%) | called by mutect2, varscan2
- TRBV19 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- APIP | c.570A>T p.V190= | Silent (SNP) | VAF 107/345 reads (31%) | catalogued as COSV53508722; called by muse, mutect2, varscan2
- ASAH2 | c.987G>A p.E329= | Silent (SNP) | VAF 108/436 reads (25%) | catalogued as COSV61484549; called by muse, mutect2, varscan2
- COL4A5 | c.3165C>G p.S1055= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV60373006, COSV60374636; called by muse, mutect2, varscan2
- CTDSPL2 | c.838T>C p.L280= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV52948760; called by muse, mutect2, varscan2
- CYP4B1 | c.192G>A p.T64= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs760448256, COSV54721123, COSV99597149; called by muse, mutect2, varscan2
- EFL1 | c.357T>A p.A119= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV51610411; called by muse, mutect2, varscan2
- FAM135B | c.1848T>C p.S616= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as COSV52755756; called by muse, mutect2, varscan2
- FAM199X | c.138C>T p.F46= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1556374100, COSV72419797; called by muse, mutect2, varscan2
- KDM4C | c.1614C>T p.G538= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV67193600; called by muse, mutect2, varscan2
- NR0B2 | c.678C>T p.S226= | Silent (SNP) | VAF 80/282 reads (28%) | catalogued as rs902095341, COSV54260245; called by muse, mutect2, varscan2
- NRG1 | c.735C>T p.T245= (on ENST00000405005 / NM_013964.5; = p.T250= on NM_013956.5) | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV55177358, COSV99828525; called by muse, mutect2, varscan2
- OR51S1 | c.321A>T p.L107= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as COSV59060335; called by muse, mutect2, varscan2
- OR6N2 | c.627C>A p.I209= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV59413313; called by muse, mutect2, varscan2
- PCDHB8 | c.2109C>T p.L703= | Silent (SNP) | VAF 103/343 reads (30%) | catalogued as COSV50820859; called by muse, mutect2, varscan2
- POMT1 | c.550C>T p.L184= | Silent (SNP) | VAF 67/231 reads (29%) | catalogued as rs1430384695, COSV61227941; called by muse, mutect2, varscan2
- RELN | c.5499C>A p.I1833= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV58999790, COSV59036193; called by muse, mutect2, varscan2
- SENP1 | c.1401T>C p.N467= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV50307447; called by muse, mutect2, varscan2
- SOX9 | c.72C>G p.P24= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV55429401; called by muse, mutect2, varscan2
- TP63 | c.516A>G p.P172= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV53222329; called by muse, mutect2, varscan2
- UNC13C | c.2811C>G p.P937= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV52928393; called by muse, mutect2, varscan2
- UNC79 | c.5934C>T p.S1978= (on ENST00000393151 / NM_001346218.2; = p.S1801= on NM_020818.5) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs868041468, COSV56413347; called by muse, mutect2, varscan2
- UTP14A | c.1282C>A p.R428= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV64087944; called by muse, mutect2, varscan2
- ZFHX4 | c.8535G>T p.L2845= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV50829937; called by muse, mutect2, varscan2
- MIR542 | n.52T>A | RNA (SNP) | VAF 101/378 reads (27%) | called by muse, mutect2, varscan2
- MIR542 | n.51C>G | RNA (SNP) | VAF 100/375 reads (27%) | called by muse, mutect2, varscan2
- MYADM | chr19:53874154 G>T | 3'Flank (SNP) | VAF 91/313 reads (29%) | catalogued as rs533715842, COSV61241077; called by muse, mutect2, varscan2
- NACA | c.70+3048A>T | Intron (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100771783; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 23/59 reads (39%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
